FM case AD9721 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/ceb86dc6-9eea-4c17-8bbd-6ad29c7f59bb

Female, 64.3 years: Pheochromocytoma, NOS (ICD-O-3 8700/0) of the adrenal gland; metastasis biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
